Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A2Q7, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A2Q7-01A (Primary Tumor).

[page 1 of 3]
Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type: INPATIENT
Additional Copy to:

Clinical Diagnosis & History:

Bilateral thyroid nodules with FNA of left lobe showing papillary thyroid carcinoma. Bilateral nodule.

Specimens Submitted:

- 1: Left thyroid lobe and isthmus
- 2: Right thyroid lobe
- 3: Left neck level six and seven lymph nodes

DIAGNOSIS:

1. Left thyroid lobe and isthmus:

Tumor Type:

Papillary carcinoma, classical type

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Other Tumor Features:

Psammoma bodies

Tumor Location:

Left lobe

Tumor Size:

Greatest diameter is 2.5 cm.

Tumor Encapsulation:

None Identified

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Invades: extrathyroidal fibrous tissue
focal

Surgical Margins:

Tumor is noted focally at the inked anterior margin

Tumor Multicentricity:

Two foci of papillary microcarcinoma in the isthmus and left lobe measuring 0.7 cm and 0.25 cm, respectively

[page 2 of 3]
Non-Neoplastic Thyroid:

Exhibits nodular hyperplasia
Exhibits mild chronic lymphocytic thyroiditis

Parathyroid Glands:

See part 3

Lymph Nodes:

One benign lymph node (0/1)

Comment: The non-neoplastic thyroid shows psammoma bodies.

2. Right thyroid lobe:

Tumor Type:

Papillary microcarcinoma, three foci

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Tumor Location:

Right lobe

Tumor Size:

The tumor foci range from 0.2 cm to 0.5 cm in greatest dimension

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Microscopic and gross foci present

Non-Neoplastic Thyroid:

Exhibits nodular hyperplasia
Exhibits mild chronic lymphocytic thyroiditis

Parathyroid Glands:

See part 3

Lymph Nodes:

Psammoma bodies are noted in 1/2 lymph nodes consistent with metastatic papillary carcinoma (1/2)

Comment: The non-neoplastic thyroid shows psammoma bodies.

3. Left neck level six and seven lymph nodes:

Lymph Node Dissection:

Metastatic papillary carcinoma
Number of lymph nodes examined: 2
Number of lymph nodes with metastatic disease: 2
Size of the largest lymph node involved by tumor: 0.8cm.
Size of the largest metastatic focus : 0.6 cm.
Extranodal extension is not identified
Unremarkable parathyroid tissue present

[page 3 of 3]
I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

M.D.
*** Report Electronically Signed Out ***

Gross Description:

M.D.

1) The specimen is received fresh labeled "Left thyroid lobe and isthmus". It consists of a thyroid lobe and isthmus measuring 4.5 x 2.5 x 2.2 cm and weighing 15 g. The surface shows nodularity. The lobe is inked black posterior and blue anterior. Serial sectioning reveals a 2.5 x 2.3 x 2.2 cm solid white well circumscribed gritty nodule in the mid to lower lobe (N1) and a 0.7 cm encapsulated tan nodule in the isthmus (N2). The specimen is entirely submitted to include TPS from the larger nodule.

Summary of sections:

N1 - nodule 1

N2 - nodule 2

RS - remaining sections

M.D.

2) The specimen is received fresh and is labeled "Right thyroid lobe". It consists of a thyroid lobe measuring 4.6 x 3 x 1.7 cm and weighing 11 g. The surface shows nodularity. The lobe is inked black posterior and blue anterior. Serial sectioning reveals multiple nodules with the largest one measuring 1 x 0.8 x 0.5 cm located in the upper lobe (N). The other nodules are all less than 0.5 cm. The specimen is entirely submitted to include TPS from the largest nodule.

Summary of sections:

N - nodule

SS - sequential remaining sections

3) The specimen is received fresh, labeled "Left neck level six and seven lymph nodes" and consists of a portion of adipose tissue in which a 1 cm grossly involved lymph node is found. Portion of this node is submitted to TPS. The remaining half of it as well as two possible lymph nodes are submitted.

Summary of sections:

LN - lymph nodes (TPS-ed node in blue)

Summary of Sections:

Part 1: Left thyroid lobe and isthmus

Block	Sect. Site	PCs
4	N1	4
1	N2	2
3	RS	3

Part 2: Right thyroid lobe

Block	Sect. Site	PCs
1	N	1
7	SS	7

Part 3: Left neck level six and seven lymph nodes

Block	Sect. Site	PCs
1	LN	3

Source: NCI Genomic Data Commons file ef7f1d0a-37b8-44b4-b146-1df8fc8ee468 (TCGA-DJ-A2Q7.2C3553C3-902B-4783-A474-332877823538.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).